Somatic mutation profile of tumor specimen HCM-CSHL-0062-C18-01A (aliquot HCM-CSHL-0062-C18-01A-01D-A768-36) from HCMI case HCM-CSHL-0062-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 70.6 years (25,784 days).
Specimen HCM-CSHL-0062-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75d323fa-3574-4ec4-a97f-c8c9db6f04dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0062-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0062-C18-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4b46cf8-b0c0-48d8-ba55-264d1372019e

The open-access MAF lists 157 somatic variants for this specimen: 103 protein-altering or splice-affecting, 39 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 39, Nonsense Mutation 13, Intron 8, Splice Site 3, Frame Shift Del 3, In Frame Del 3, 3'UTR 3, 5'Flank 2, Splice Region 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3549T>G p.Y1183* | Nonsense Mutation (SNP) | VAF 104/303 reads (34%) | catalogued as rs1561585641, COSV57333455; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 138/349 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 175/362 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 49/157 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as rs200621947; called by muse, mutect2, varscan2
- APC | c.1206del p.E403Kfs*51 | Frame Shift Del (DEL) | VAF 52/153 reads (34%) | catalogued as COSV57351508; called by mutect2, pindel, varscan2
- APCDD1L | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs923267133, COSV100953923; called by muse, mutect2, varscan2
- ATXN2 | c.3809C>T p.T1270M (on ENST00000550104; = p.T1110M on NM_002973.4) | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as rs1276087803; called by muse, mutect2, varscan2
- BCL9L | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV104403427; called by muse, varscan2
- CBARP | c.2008G>A p.G670R | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV99289524; called by muse, mutect2, varscan2
- CEP290 | c.4678C>T p.Q1560* | Nonsense Mutation (SNP) | VAF 105/404 reads (26%) | catalogued as rs1167696567; called by muse, mutect2, varscan2
- CHD4 | c.2885G>A p.R962H (on ENST00000357008 / NM_001363606.2; = p.R975H on NM_001273.5) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58896611, COSV58901386; called by muse, mutect2, varscan2
- CLIP2 | c.2285_2287del p.K762del | In Frame Del (DEL) | VAF 88/310 reads (28%) | catalogued as rs1273300405; called by pindel, varscan2
- CNKSR2 | c.2392G>A p.A798T | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs755412341, COSV54258773; called by muse, mutect2, varscan2
- CNNM1 | c.2176+1G>A p.X726_splice | Splice Site (SNP) | VAF 69/159 reads (43%) | catalogued as rs376631525; called by muse, mutect2, varscan2
- CNTN5 | c.3275C>A p.A1092E | Missense Mutation (SNP) | VAF 110/366 reads (30%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.505); catalogued as COSV54320087; called by muse, varscan2
- COL5A1 | c.5194C>T p.R1732W | Missense Mutation (SNP) | VAF 26/477 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201379514, COSV65674242; called by muse, mutect2
- CPE | c.1289C>A p.A430E | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.316); catalogued as rs1301681242, COSV101291606; called by muse, mutect2, varscan2
- CXorf56 | c.587C>T p.A196V (on ENST00000536133 / NM_001170570.2; = p.A210V on NM_022101.4) | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.281); catalogued as rs764134233, COSV100233328; called by muse, mutect2, varscan2
- DMBT1 | c.7441C>T p.R2481C (on ENST00000338354 / NM_001377530.1; = p.R1724C on NM_004406.3) | Missense Mutation (SNP) | VAF 95/288 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1034308642, COSV57533768; called by muse, mutect2, varscan2
- DNHD1 | c.9284C>T p.S3095L | Missense Mutation (SNP) | VAF 136/389 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs975437665, COSV54433720; called by muse, mutect2, varscan2
- DOK6 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 77/267 reads (29%) | catalogued as COSV101234236; called by muse, mutect2, varscan2
- DPY19L2 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as rs1234570183; called by muse, mutect2
- ECE1 | c.2017G>A p.G673R | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1376227095, COSV51663176; called by muse, mutect2, varscan2
- EEF1G | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 173/428 reads (40%) | catalogued as COSV61323157; called by muse, mutect2, varscan2
- EI24 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1565331774, COSV54020314; called by muse, mutect2, varscan2
- EPAS1 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 180/540 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs1440594107; called by muse, mutect2, varscan2
- ERICH3 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377323449; called by muse, mutect2, varscan2
- FMR1 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 91/221 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.111); catalogued as rs1557182644, COSV54424209; called by muse, mutect2, varscan2
- GIPC2 | c.281A>G p.E94G | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs771637259; called by muse, mutect2
- GPER1 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 125/315 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1223808410; called by muse, mutect2, varscan2
- HOXC13 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV54499996; called by muse, mutect2
- IFT140 | c.2423C>T p.A808V | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs748463111, COSV54153601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INTS5 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs887202407; called by muse, mutect2, varscan2
- ITGB4 | c.4336C>T p.R1446W | Missense Mutation (SNP) | VAF 146/414 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs1299766746; called by muse, mutect2, varscan2
- JAKMIP2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 173/440 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs774610220, COSV54597568; called by muse, mutect2, varscan2
- KCNC2 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 131/468 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as rs757081755; called by muse, mutect2, varscan2
- KIF21B | c.1212G>A p.A404= | Splice Region (SNP) | VAF 136/364 reads (37%) | catalogued as rs371524692; called by muse, mutect2
- KLHL7 | c.1214C>T p.T405M (on ENST00000339077 / NM_001031710.3; = p.T357M on NM_018846.5) | Missense Mutation (SNP) | VAF 20/450 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV59163472; called by muse, mutect2
- LIN28A | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 80/263 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs749687753, COSV54261112; called by muse, mutect2, varscan2
- MBOAT1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752753742; called by muse, mutect2, varscan2
- MED12L | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 57/154 reads (37%) | catalogued as COSV56388924; called by muse, mutect2, varscan2
- NBPF11 | c.122_123del p.R41Mfs*20 | Frame Shift Del (DEL) | VAF 89/496 reads (18%) | catalogued as rs1229366144; called by pindel, varscan2
- NCAM1 | c.1763C>T p.A588V (on ENST00000316851 / NM_181351.5; = p.A578V on NM_000615.7) | Missense Mutation (SNP) | VAF 13/235 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57516657; called by muse, mutect2
- NRCAM | c.2359C>T p.R787C (on ENST00000379028 / NM_001371124.1; = p.R771C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/323 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769341831, COSV61043555; called by muse, mutect2, varscan2
- OLR1 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 58/104 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs374494106, COSV100376305; called by muse, mutect2, varscan2
- OR4A15 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 99/276 reads (36%) | catalogued as rs150217199, COSV100123812; called by muse, mutect2, varscan2
- OR7D2 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.305); catalogued as rs767692324; called by muse, mutect2, varscan2
- PCDH19 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 188/586 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM162899, COSV55271064, COSV99721011; called by muse, mutect2, varscan2
- PCDHA11 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 213/611 reads (35%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.005); catalogued as COSV100250531; called by muse, mutect2, varscan2
- PCDHB14 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 58/1080 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); catalogued as COSV99505551; called by muse, mutect2
- PCSK4 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs775454627, COSV52012379; called by muse, mutect2, varscan2
- PIK3CG | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 106/313 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1226994105, COSV63247193; called by muse, mutect2, varscan2
- PIP4K2C | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 147/637 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs973052423, COSV100533807; called by muse, mutect2, varscan2
- PSMA3 | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99373520; called by muse, mutect2, varscan2
- RBM20 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 176/538 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs766868824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBMXL2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.569); catalogued as rs866421802; called by muse, mutect2, varscan2
- RBMXL3 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs1556560828; called by muse, mutect2, varscan2
- RHBDF2 | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 106/264 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs1196107833, COSV99166265; called by muse, mutect2, varscan2
- SIN3A | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.795); catalogued as rs757121084; called by muse, mutect2
- TLR9 | c.2182C>T p.R728* | Nonsense Mutation (SNP) | VAF 35/91 reads (38%) | catalogued as rs1013859585, COSV62345876; called by muse, mutect2, varscan2
- TMEM132C | c.3100C>T p.R1034W | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs369408255, COSV59430525; called by muse, mutect2, varscan2
- USP6 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 31/658 reads (5%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.713); catalogued as rs1419592864; called by muse, mutect2
- WNT3 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 111/266 reads (42%) | catalogued as COSV56644576; called by muse, mutect2, varscan2
- ANKRD29 | c.712G>C p.G238R | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by mutect2, varscan2
- ANOS1 | c.1063-1G>A p.X355_splice | Splice Site (SNP) | VAF 94/239 reads (39%) | called by muse, mutect2, varscan2
- AUTS2 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- BCL9 | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 43/114 reads (38%) | called by muse, mutect2, varscan2
- C7orf26 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 29/304 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- C8orf48 | c.396G>C p.L132F | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CACNA2D1 | c.1172A>C p.Q391P | Missense Mutation (SNP) | VAF 93/268 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CFAP69 | c.2574A>T p.K858N | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CST6 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 56/152 reads (37%) | called by muse, mutect2, varscan2
- DHTKD1 | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELMO3 | c.960dup p.I321Hfs*67 (on ENST00000652269; = p.I268Hfs*67 on NM_024712.5) | Frame Shift Ins (INS) | VAF 47/145 reads (32%) | called by mutect2, pindel, varscan2
- EPHA2 | c.1683-1G>T p.X561_splice | Splice Site (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- FOXD3 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- GON4L | c.2947C>T p.P983S | Missense Mutation (SNP) | VAF 128/354 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HGF | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 95/337 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTRA1 | c.866A>G p.Q289R | Missense Mutation (SNP) | VAF 121/349 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IRAG2 | c.3857G>T p.G1286V (on ENST00000636465; = p.G331V on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- LRP2 | c.7148C>T p.A2383V | Missense Mutation (SNP) | VAF 121/354 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRP4 | c.4357G>A p.E1453K | Missense Mutation (SNP) | VAF 144/507 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MAP9 | c.979A>G p.R327G | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MTMR4 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MYCBP2 | c.5146C>T p.P1716S (on ENST00000357337; = p.P1754S on NM_015057.5) | Missense Mutation (SNP) | VAF 148/556 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NBEA | c.6726del p.D2243Ifs*5 | Frame Shift Del (DEL) | VAF 50/202 reads (25%) | called by mutect2, pindel, varscan2
- ONECUT2 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 122/342 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); called by muse, varscan2
- OR2G6 | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2
- PLOD2 | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- SLC24A4 | c.1220T>C p.V407A | Missense Mutation (SNP) | VAF 115/347 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORCS1 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOX9 | c.367_378del p.L123_Q126del | In Frame Del (DEL) | VAF 45/188 reads (24%) | called by mutect2, pindel, varscan2
- SP100 | c.2279G>C p.G760A | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TACR3 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 90/249 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TAS1R2 | c.1132A>T p.R378W | Missense Mutation (SNP) | VAF 169/381 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- TDRD15 | c.2998G>T p.E1000* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- TMUB2 | c.467A>G p.E156G (on ENST00000538716 / NM_001353177.2; = p.E136G on NM_024107.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/249 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- TRADD | c.268_291del p.Y90_A97del | In Frame Del (DEL) | VAF 105/274 reads (38%) | called by mutect2, pindel
- TRPV3 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- TTI1 | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 181/350 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZC3H12D | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 29/353 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2
- ZIK1 | c.328A>G p.K110E | Missense Mutation (SNP) | VAF 19/348 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2
- ACSS2 | c.105C>T p.V35= | Silent (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2
- ADAD2 | c.1413G>A p.P471= (on ENST00000315906 / NM_001145400.2; = p.P553= on NM_139174.4) | Silent (SNP) | VAF 93/270 reads (34%) | catalogued as rs1022671732, COSV99235229; called by muse, mutect2, varscan2
- ADAMTS9 | c.1974C>T p.D658= | Silent (SNP) | VAF 62/193 reads (32%) | catalogued as rs754577175, COSV55777195; called by muse, mutect2, varscan2
- AGGF1 | c.96G>A p.L32= | Silent (SNP) | VAF 219/611 reads (36%) | catalogued as rs751836536; called by muse, mutect2, varscan2
- ALG14 | c.30C>T p.A10= | Silent (SNP) | VAF 85/266 reads (32%) | called by muse, varscan2
- CELA2B | c.678C>T p.D226= | Silent (SNP) | VAF 32/310 reads (10%) | catalogued as rs777716220; called by muse, mutect2
- CHFR | c.1509G>A p.P503= (on ENST00000432561 / NM_001161345.1; = p.P462= on NM_018223.2) | Silent (SNP) | VAF 64/230 reads (28%) | catalogued as rs142511371; called by muse, mutect2, varscan2
- COL4A6 | c.2364C>T p.H788= | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as rs375971196, COSV57881919; called by muse, mutect2
- DNAH17 | c.141C>T p.P47= | Silent (SNP) | VAF 143/364 reads (39%) | catalogued as rs370459386; called by muse, mutect2, varscan2
- DNAH9 | c.3249C>T p.G1083= | Silent (SNP) | VAF 142/449 reads (32%) | called by muse, mutect2, varscan2
- DRAXIN | c.708C>T p.T236= | Silent (SNP) | VAF 122/331 reads (37%) | catalogued as rs555747838; called by muse, mutect2, varscan2
- FRYL | c.8658C>T p.S2886= | Silent (SNP) | VAF 25/86 reads (29%) | catalogued as rs375724636; called by muse, mutect2, varscan2
- IFNA1 | c.330C>T p.T110= | Silent (SNP) | VAF 38/201 reads (19%) | catalogued as rs774504120; called by muse, mutect2, varscan2
- INA | c.696C>T p.D232= | Silent (SNP) | VAF 99/272 reads (36%) | called by muse, mutect2, varscan2
- KLHL34 | c.1578C>T p.G526= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV101069938; called by muse, mutect2, varscan2
- KRTAP23-1 | c.144A>G p.P48= | Silent (SNP) | VAF 127/426 reads (30%) | catalogued as COSV100492636; called by muse, mutect2, varscan2
- LCE1F | c.81G>A p.P27= | Silent (SNP) | VAF 114/316 reads (36%) | catalogued as rs759179642, COSV57668723; called by muse, mutect2, varscan2
- LILRB1 | c.198C>A p.T66= (on ENST00000427581; = p.T30= on NM_006669.6) | Silent (SNP) | VAF 37/174 reads (21%) | catalogued as rs540151068; called by muse, mutect2, varscan2
- MACF1 | c.15009G>T p.L5003= (on ENST00000372915; = p.L2936= on NM_012090.5) | Silent (SNP) | VAF 76/187 reads (41%) | called by muse, mutect2, varscan2
- MAGEC1 | c.3288T>C p.P1096= | Silent (SNP) | VAF 59/162 reads (36%) | called by muse, mutect2, varscan2
- MAN2C1 | c.207C>G p.V69= | Silent (SNP) | VAF 78/191 reads (41%) | called by muse, mutect2, varscan2
- MYBPC2 | c.1290C>T p.A430= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as rs749900428; called by muse, mutect2, varscan2
- NKX6-2 | c.639G>A p.S213= | Silent (SNP) | VAF 172/520 reads (33%) | called by muse, mutect2, varscan2
- NMNAT2 | c.378C>T p.I126= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as rs201999438; called by muse, mutect2, varscan2
- OLIG2 | c.51C>T p.P17= | Silent (SNP) | VAF 145/421 reads (34%) | called by muse, mutect2, varscan2
- P2RY8 | c.888G>A p.A296= | Silent (SNP) | VAF 155/423 reads (37%) | catalogued as COSV67177132; called by muse, mutect2, varscan2
- PDS5A | c.2787G>A p.R929= | Silent (SNP) | VAF 96/235 reads (41%) | called by muse, mutect2, varscan2
- PRR23A | c.387C>T p.G129= | Silent (SNP) | VAF 95/236 reads (40%) | catalogued as rs368434952; called by muse, mutect2, varscan2
- RSPRY1 | c.1200G>T p.A400= | Silent (SNP) | VAF 103/310 reads (33%) | called by muse, mutect2, varscan2
- SARDH | c.522G>A p.A174= | Silent (SNP) | VAF 53/145 reads (37%) | called by muse, mutect2
- SMO | c.807C>T p.Y269= | Silent (SNP) | VAF 56/170 reads (33%) | catalogued as rs200677912, COSV99977207; called by muse, mutect2, varscan2
- SOWAHD | c.81G>A p.P27= | Silent (SNP) | VAF 82/202 reads (41%) | called by muse, mutect2, varscan2
- TLNRD1 | c.546G>A p.E182= | Silent (SNP) | VAF 53/142 reads (37%) | catalogued as rs572653982; called by muse, mutect2, varscan2
- TMEM121 | c.144C>T p.G48= | Silent (SNP) | VAF 24/490 reads (5%) | catalogued as rs782684743, COSV66796694; called by muse, mutect2
- TYW5 | c.69C>G p.L23= | Silent (SNP) | VAF 57/185 reads (31%) | called by muse, mutect2, varscan2
- VWA3A | c.285G>A p.S95= | Silent (SNP) | VAF 7/150 reads (5%) | catalogued as rs1357123728; called by muse, mutect2
- WASF3 | c.1125C>A p.A375= | Silent (SNP) | VAF 37/386 reads (10%) | called by muse, mutect2
- WDR18 | c.516G>A p.A172= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as rs1007494180, COSV99242635; called by muse, mutect2, varscan2
- ZNF521 | c.3037T>C p.L1013= | Silent (SNP) | VAF 45/122 reads (37%) | called by muse, mutect2, varscan2
- ANO1 | c.2198-823G>A | Intron (SNP) | VAF 20/56 reads (36%) | catalogued as rs1368114518; called by muse, varscan2
- ARHGEF25 | chr12:57610631 G>T | 5'Flank (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- BCAT1 | c.7-1083C>T | Intron (SNP) | VAF 60/247 reads (24%) | called by muse, mutect2, varscan2
- BIN2 | chr12:51324557 C>T | 5'Flank (SNP) | VAF 5/40 reads (13%) | catalogued as rs1407065312; called by muse, mutect2, varscan2
- FOXP2 | c.*3151T>G | 3'UTR (SNP) | VAF 61/161 reads (38%) | called by muse, mutect2, varscan2
- GRIK1 | c.1251+146A>G | Intron (SNP) | VAF 88/235 reads (37%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1377+40C>T | Intron (SNP) | VAF 105/364 reads (29%) | catalogued as rs746545872; called by muse, mutect2, varscan2
- MAU2 | c.*53C>T | 3'UTR (SNP) | VAF 184/543 reads (34%) | catalogued as rs940624920; called by muse, mutect2, varscan2
- NAA60 | c.*207-40G>A | Intron (SNP) | VAF 38/116 reads (33%) | catalogued as rs766364207; called by muse, mutect2, varscan2
- PAX3 | c.-20C>T | 5'UTR (SNP) | VAF 87/258 reads (34%) | catalogued as rs1469006207, COSV51345776; called by muse, mutect2, varscan2
- POLA1 | c.2947-21311G>A | Intron (SNP) | VAF 90/298 reads (30%) | catalogued as rs1370942836, COSV66891326; called by muse, mutect2, varscan2
- PRICKLE3 | c.43-40G>A | Intron (SNP) | VAF 90/295 reads (31%) | called by muse, mutect2, varscan2
- PRPF8 | c.3774+11G>A | Intron (SNP) | VAF 181/473 reads (38%) | catalogued as rs762203625; called by muse, mutect2, varscan2
- SLC9A3R2 | c.*513C>T | 3'UTR (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- TCP10L3 | n.469C>T | RNA (SNP) | VAF 85/310 reads (27%) | catalogued as rs1190388784; called by muse, mutect2, varscan2
